Somatic mutation profile of tumor specimen TCGA-QK-A6IJ-01A (aliquot TCGA-QK-A6IJ-01A-11D-A31L-08) from TCGA case TCGA-QK-A6IJ, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 71.1 years (25,966 days).
Specimen TCGA-QK-A6IJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36fa306c-4b4d-468c-a50f-db7f02dfc456.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QK-A6IJ-10A (Blood Derived Normal), aliquot TCGA-QK-A6IJ-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/922bac80-8cb7-461f-80eb-e819f3978d2e

The open-access MAF lists 66 somatic variants for this specimen: 48 protein-altering or splice-affecting, 14 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 14, Nonsense Mutation 6, RNA 3, Splice Site 3, Frame Shift Ins 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA1 | c.3589G>T p.V1197L | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.082); catalogued as COSV101036962; called by muse, mutect2
- ACTR3B | c.380C>A p.A127E | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99754063; called by muse, mutect2
- ANO4 | c.2818C>T p.R940* (on ENST00000392977 / NM_001286615.2; = p.R905* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 3/49 reads (6%) | catalogued as rs763133235; called by muse, mutect2
- ASXL2 | c.4304G>A p.R1435Q | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs542810776, COSV55467976; called by muse, mutect2, varscan2
- BICC1 | c.445G>A p.G149S | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100874850, COSV100874863; called by muse, mutect2
- BUB1B | c.506G>A p.R169K | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55018618; called by muse, mutect2
- CDKN2A | c.28G>T p.E10* | Nonsense Mutation (SNP) | VAF 29/42 reads (69%) | catalogued as COSV58705987; called by muse, mutect2, varscan2
- CENPF | c.1690G>T p.E564* | Nonsense Mutation (SNP) | VAF 28/198 reads (14%) | catalogued as COSV100871693; called by muse, mutect2, varscan2
- CHD6 | c.7131+1G>C p.X2377_splice | Splice Site (SNP) | VAF 11/131 reads (8%) | catalogued as COSV100950998; called by muse, mutect2
- COPA | c.1600G>A p.A534T | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.654); catalogued as rs1263561347, COSV54105625; called by muse, mutect2, varscan2
- CREBBP | c.4262G>T p.C1421F | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52138366, COSV99269455; called by muse, mutect2, varscan2
- CTIF | c.463G>A p.G155S | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.007); catalogued as rs1568121452, COSV56492269, COSV99837551; called by muse, mutect2
- DDX11 | c.1208C>T p.T403M | Missense Mutation (SNP) | VAF 13/159 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs766443735, COSV52504878; called by muse, mutect2
- DUOX2 | c.4240-1G>T p.X1414_splice | Splice Site (SNP) | VAF 5/39 reads (13%) | catalogued as COSV101199771; called by muse, mutect2, varscan2
- ENOX2 | c.1688G>A p.R563H (on ENST00000338144 / NM_001382520.1; = p.R534H on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/201 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs770410543, COSV100584147; called by muse, mutect2, varscan2
- GDF5 | c.205dup p.A69Gfs*25 | Frame Shift Ins (INS) | VAF 45/61 reads (74%) | catalogued as rs753691079; called by mutect2, varscan2
- GRXCR1 | c.844C>T p.L282F | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1414314632, COSV101295690, COSV67674123; called by muse, mutect2
- IL9R | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 10/177 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs768939941, COSV99729778; called by muse, mutect2
- KCNH6 | c.1609C>G p.R537G | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as COSV100121054, COSV59001261, COSV59003252; called by muse, mutect2, varscan2
- LIN7A | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as COSV54021522; called by muse, mutect2, varscan2
- MRPL44 | c.910C>G p.L304V | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.73); catalogued as COSV99285217; called by muse, mutect2
- NLN | c.439G>T p.V147F | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as COSV101114278; called by muse, mutect2, varscan2
- PCDH10 | c.329T>A p.I110N | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV99993575; called by muse, mutect2
- PCDH10 | c.947T>G p.L316W | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99993577; called by muse, mutect2
- PCDHA13 | c.1514C>T p.S505L | Missense Mutation (SNP) | VAF 27/171 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV56475108; called by muse, mutect2, varscan2
- PCDHB2 | c.2102C>T p.S701L | Missense Mutation (SNP) | VAF 30/279 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.052); catalogued as COSV99165209; called by muse, mutect2, varscan2
- PCDHGA2 | c.220C>A p.L74I | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.248); catalogued as COSV53938063, COSV99538431; called by muse, mutect2, varscan2
- PCGF1 | c.424+1G>A p.X142_splice | Splice Site (SNP) | VAF 54/223 reads (24%) | catalogued as COSV99283321; called by muse, mutect2, varscan2
- PDHA2 | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.036); catalogued as COSV54776936, COSV54781887; called by muse, mutect2
- POTEE | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.141); catalogued as rs1251130356, COSV58223535; called by muse, mutect2
- PTP4A3 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 27/210 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs780282009, COSV100267224; called by muse, mutect2, varscan2
- RBL2 | c.1497C>G p.Y499* | Nonsense Mutation (SNP) | VAF 15/52 reads (29%) | catalogued as COSV100043634; called by muse, mutect2, varscan2
- RBM19 | c.671C>A p.S224* | Nonsense Mutation (SNP) | VAF 12/102 reads (12%) | catalogued as COSV55689351, COSV99926096; called by muse, mutect2, varscan2
- RIMS2 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755807622, COSV68472575; called by muse, mutect2, varscan2
- SBK1 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 40/193 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100543522; called by muse, mutect2, varscan2
- SIPA1L1 | c.4157G>A p.R1386Q | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.536); catalogued as rs575226257, COSV62171402; called by muse, mutect2, varscan2
- SLC16A14 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV54618869; called by muse, mutect2
- SLK | c.3553A>G p.R1185G | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100211763; called by muse, mutect2
- SORL1 | c.1765G>A p.E589K | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99493887; called by muse, mutect2
- SPP1 | c.638C>T p.A213V (on ENST00000395080 / NM_001040058.2; = p.A199V on NM_000582.2) | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1263552254, COSV52952880; called by muse, mutect2, varscan2
- TP53 | c.531_532dup p.H178Pfs*70 | Frame Shift Ins (INS) | VAF 30/78 reads (38%) | catalogued as COSV99408054; called by mutect2, pindel, varscan2
- TRPV5 | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV99520550; called by muse, mutect2
- UBR4 | c.8741G>A p.R2914Q | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as rs147072344; called by muse, mutect2, varscan2
- VN1R4 | c.167C>G p.A56G | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs1207345505, COSV100237423; called by muse, varscan2
- ZNF786 | c.832C>T p.R278* | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | catalogued as rs757197778, COSV100302836; called by muse, mutect2, varscan2
- BTNL3 | c.70_71dup p.G25Rfs*65 | Frame Shift Ins (INS) | VAF 12/45 reads (27%) | called by mutect2, pindel, varscan2
- COL11A1 | c.3781G>C p.G1261R | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRBJ2-2 | c.23T>C p.F8S | Missense Mutation (SNP) | VAF 6/53 reads (11%) | called by muse, mutect2, varscan2
- ACACA | c.6282C>T p.Y2094= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as rs372559158; called by muse, mutect2
- ADCY8 | c.1023G>A p.L341= | Silent (SNP) | VAF 19/276 reads (7%) | catalogued as COSV99652328; called by muse, mutect2
- ARHGAP26 | c.423T>C p.Y141= | Silent (SNP) | VAF 4/58 reads (7%) | catalogued as rs1490221875, COSV99190952; called by muse, mutect2
- BMX | c.1914G>A p.S638= | Silent (SNP) | VAF 19/135 reads (14%) | catalogued as rs1353106596, COSV100564465; called by muse, mutect2, varscan2
- CEP131 | c.3195C>T p.A1065= (on ENST00000269392 / NM_001319228.2; = p.A1062= on NM_014984.4) | Silent (SNP) | VAF 17/230 reads (7%) | catalogued as rs748731729, COSV53951211; called by muse, mutect2
- CYP2B6 | c.9C>A p.L3= | Silent (SNP) | VAF 28/167 reads (17%) | catalogued as COSV100137561; called by muse, mutect2, varscan2
- FMN2 | c.1299G>A p.P433= | Silent (SNP) | VAF 12/115 reads (10%) | catalogued as COSV60425526; called by muse, mutect2, varscan2
- FRRS1L | c.705T>C p.I235= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV101643913; called by muse, mutect2, varscan2
- GGTLC1 | c.393G>A p.T131= | Silent (SNP) | VAF 33/192 reads (17%) | catalogued as rs3865760, COSV99600670; called by muse, mutect2, varscan2
- HTR1A | c.498C>T p.L166= | Silent (SNP) | VAF 14/175 reads (8%) | catalogued as COSV60500596; called by muse, mutect2
- KRT9 | c.930G>A p.E310= | Silent (SNP) | VAF 32/76 reads (42%) | catalogued as COSV99879203; called by muse, mutect2, varscan2
- MC4R | c.168C>A p.V56= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as COSV100235990; called by muse, mutect2, varscan2
- SSTR3 | c.588C>T p.P196= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs769458937, COSV100142671; called by muse, mutect2, varscan2
- ZNF648 | c.1383G>A p.S461= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as COSV60570038; called by muse, mutect2
- CR2 | c.1979-134T>A | Intron (SNP) | VAF 13/157 reads (8%) | catalogued as COSV100889639; called by muse, mutect2
- EI24P4 | n.955C>T | RNA (SNP) | VAF 23/270 reads (9%) | called by muse, mutect2
- NBPF25P | n.855C>T | RNA (SNP) | VAF 18/222 reads (8%) | catalogued as rs1303329631; called by muse, mutect2
- OR2W5 | n.498T>G | RNA (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2, varscan2
